Somatic mutation profile of tumor specimen TARGET-40-PAMRHD-01A (aliquot TARGET-40-PAMRHD-01A-01D) from TARGET case TARGET-40-PAMRHD, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 10.8 years (3,942 days).
Specimen TARGET-40-PAMRHD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc28385e-b895-4201-b96d-67a3e21410fc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMRHD-10A (Blood Derived Normal), aliquot TARGET-40-PAMRHD-10A-01Y; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/57700bf6-13c0-4d9b-b196-bcc9d5a018db

The open-access MAF lists 16 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 3, RNA 3, Intron 2, 3'Flank 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KPRP | c.749G>A p.R250Q | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs371161809; called by muse, varscan2
- MDN1 | c.14695G>A p.D4899N | Missense Mutation (SNP) | VAF 28/147 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.037); catalogued as rs752648941; called by muse, mutect2, varscan2
- MUC4 | c.11396C>A p.S3799Y | Missense Mutation (SNP) | VAF 38/568 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.049); catalogued as rs780408486; called by muse, varscan2
- NLGN1 | c.2420C>A p.T807N | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.118); catalogued as COSV100848723; called by muse, mutect2, varscan2
- NOP14 | c.1783T>G p.C595G | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PHLDB2 | c.2135C>T p.A712V (on ENST00000393925 / NM_001134439.2; = p.A669V on NM_145753.2) | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.186); called by muse, mutect2
- RB1 | c.2155_2157del p.L719del | In Frame Del (DEL) | VAF 23/40 reads (58%) | called by mutect2, pindel, varscan2
- PLXNA4 | c.1671G>A p.Q557= | Silent (SNP) | VAF 9/89 reads (10%) | called by muse, mutect2, varscan2
- SEC14L5 | c.2016C>T p.G672= | Silent (SNP) | VAF 31/90 reads (34%) | catalogued as COSV52036313; called by muse, mutect2, varscan2
- SPRY3 | c.303C>A p.A101= | Silent (SNP) | VAF 27/306 reads (9%) | called by muse, mutect2
- AGAP7P | n.2051G>A | RNA (SNP) | VAF 8/162 reads (5%) | catalogued as rs560889711; called by muse, mutect2
- ANKRD11P2 | n.413C>G | RNA (SNP) | VAF 18/62 reads (29%) | called by muse, mutect2, varscan2
- CRISP3 | chr6:49728632 A>T | 3'Flank (SNP) | VAF 12/50 reads (24%) | called by muse, mutect2, varscan2
- GMPPA | c.139-127G>T | Intron (SNP) | VAF 39/58 reads (67%) | called by muse, mutect2, varscan2
- OR4N1P | n.544C>G | RNA (SNP) | VAF 12/298 reads (4%) | catalogued as rs1460473793; called by muse, mutect2
- ROCK1 | c.3513-19G>A | Intron (SNP) | VAF 4/20 reads (20%) | catalogued as rs372367378; called by mutect2, varscan2
